Somatic mutation profile of tumor specimen TCGA-EL-A3ZS-01A (aliquot TCGA-EL-A3ZS-01A-12D-A23M-08) from TCGA case TCGA-EL-A3ZS, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 22.1 years (8,076 days).
Specimen TCGA-EL-A3ZS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f39c3a64-3dd8-43c4-82e2-19760394867e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3ZS-11A (Solid Tissue Normal), aliquot TCGA-EL-A3ZS-11A-11D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95f9e43c-0e1e-4521-839e-8b29afb24a5a

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1QL4 | c.149C>A p.P50H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV99226975; called by muse, mutect2
- KCTD9 | c.458G>C p.R153P | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55341462, COSV99648783; called by muse, mutect2, varscan2
- TTN | c.77474C>A p.P25825H (on ENST00000591111; = p.P18401H on NM_003319.4) | Missense Mutation (SNP) | VAF 7/107 reads (7%) | PolyPhen probably damaging (0.999); catalogued as COSV100625204; called by muse, mutect2
- TTN | c.59930C>T p.S19977F (on ENST00000591111; = p.S12553F on NM_003319.4) | Missense Mutation (SNP) | VAF 13/296 reads (4%) | PolyPhen probably damaging (0.939); catalogued as COSV100625207; called by muse, mutect2
